Gene-level copy-number profile of tumor specimen TCGA-91-6830-01A from TCGA case TCGA-91-6830, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.5 years (23,922 days).
Specimen TCGA-91-6830-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.afdba6d2-c5dd-494c-b997-8854e9cb770b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6830-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ed1b16c-d54c-4bed-9346-c9df6bc51cb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,623; copy number 2: 38,506; copy number 3: 1,819; copy number 5: 872.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6830-01A-11D-1943-01): tumor purity 0.28, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 872 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:16,355,239–16,472,085, 1 gene, copy number 5 (within-gene range 1–5): EPS15L1.
- chr19:16,412,684–40,426,702, 871 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,623. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
